Somatic mutation profile of tumor specimen TARGET-20-PARPDS-04A (aliquot TARGET-20-PARPDS-04A-02D) from TARGET case TARGET-20-PARPDS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,774 days).
Specimen TARGET-20-PARPDS-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f4cc6a0-13f2-43b3-832c-683ce9e68c82.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPDS-14A (Bone Marrow Normal), aliquot TARGET-20-PARPDS-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aeb7b9b-ffe7-4e3c-b895-13b8aaac3a44

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- COL12A1 | c.5951G>A p.G1984E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV59410165; called by muse, mutect2, varscan2
- NCAM1 | c.2064C>A p.N688K (on ENST00000316851 / NM_181351.5; = p.N678K on NM_000615.7) | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57517490, COSV57524923; called by muse, mutect2
